HCMI case HCM-CSHL-0464-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fc25bee8-d37a-4bda-9ff3-51fe590e91e8

Demographics
Sex at birth: female; Year of birth: 1976; Vital status: Alive.

Diagnoses (1)
1. Intraductal carcinoma, noninfiltrating, NOS: ICD-O-3 morphology code: 8500/2; ICD-10 code: C50.0; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 42.0 years (15,330 days); AJCC pathologic T: T2; AJCC pathologic N: N1a; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 39 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 0, day 60.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- PGR (IHC): Positive.

Other clinical attributes
- Day 0: Menopause status: Premenopausal.
- Timepoint category: Initial Diagnosis; Weight: 57 kg; Height: 171 cm; BMI: 19.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0464-C50-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0464-C50-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
